Somatic mutation profile of tumor specimen TCGA-BA-4074-01A (aliquot TCGA-BA-4074-01A-01D-1434-08) from TCGA case TCGA-BA-4074, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Tongue, NOS; AJCC pathologic stage: Stage IVA; Tumor grade: G3; Age at diagnosis: 69.2 years (25,282 days).
Specimen TCGA-BA-4074-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ff2fe45b-c8f3-4a31-a075-3297d120eb13.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-BA-4074-10A (Blood Derived Normal), aliquot TCGA-BA-4074-10A-01D-1434-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/40d541cf-3179-4e9e-9e07-cffd3ce622a7

The open-access MAF lists 158 somatic variants for this specimen: 122 protein-altering or splice-affecting, 34 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 101, Silent 34, Nonsense Mutation 8, Frame Shift Ins 7, Frame Shift Del 2, Splice Site 2, Translation Start Site 1, Splice Region 1, RNA 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PTEN | c.511C>T p.Q171* | Nonsense Mutation (SNP) | VAF 76/195 reads (39%) | hotspot (GDC flag); catalogued as rs786204864, CM142087, HM971504, COSV64288951, COSV64296078, COSV64302138; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TP53 | c.774A>T p.E258D | Missense Mutation (SNP) | VAF 34/71 reads (48%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen possibly damaging (0.903); catalogued as COSV52752502, COSV52980614; called by muse, mutect2, varscan2
- ABCA12 | c.131G>A p.R44Q | Missense Mutation (SNP) | VAF 34/137 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.078); catalogued as rs113648834, COSV99792281; called by muse, mutect2, varscan2
- ACSBG2 | c.1867C>T p.Q623* | Nonsense Mutation (SNP) | VAF 60/227 reads (26%) | catalogued as COSV99397681; called by muse, mutect2, varscan2
- ACTL6A | c.310G>A p.D104N | Missense Mutation (SNP) | VAF 49/155 reads (32%) | SIFT tolerated (0.13); PolyPhen benign (0.038); catalogued as COSV101199750, COSV66999424; called by muse, mutect2, varscan2
- ADD1 | c.601A>C p.N201H | Missense Mutation (SNP) | VAF 17/52 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV99297126; called by muse, varscan2
- ADGRB3 | c.1880C>A p.T627K | Missense Mutation (SNP) | VAF 50/178 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV101002032; called by muse, mutect2, varscan2
- ADGRL2 | c.2777C>A p.A926D (on ENST00000370717 / NM_001366005.1; = p.A913D on NM_012302.4) | Missense Mutation (SNP) | VAF 70/341 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.261); catalogued as COSV99591829; called by muse, mutect2, varscan2
- AKT3 | c.1028G>T p.R343M | Missense Mutation (SNP) | VAF 55/353 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as COSV99797025; called by muse, mutect2, varscan2
- ANKRD36 | c.150C>G p.Y50* | Nonsense Mutation (SNP) | VAF 30/88 reads (34%) | catalogued as COSV101347555; called by muse, mutect2, varscan2
- ANKS3 | c.1855G>A p.E619K | Missense Mutation (SNP) | VAF 52/190 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.207); catalogued as rs187743929; called by muse, mutect2, varscan2
- ARHGAP17 | c.604A>C p.M202L | Missense Mutation (SNP) | VAF 40/159 reads (25%) | SIFT tolerated (0.13); PolyPhen benign (0.029); catalogued as COSV99253045, COSV99254131; called by muse, mutect2, varscan2
- ARHGAP29 | c.2367G>C p.W789C | Missense Mutation (SNP) | VAF 30/152 reads (20%) | SIFT tolerated (0.18); PolyPhen benign (0.295); catalogued as CM153306, COSV99559158; called by muse, mutect2, varscan2
- ASCC3 | c.5431G>A p.E1811K | Missense Mutation (SNP) | VAF 65/246 reads (26%) | SIFT tolerated (0.55); PolyPhen benign (0.039); catalogued as COSV100976841, COSV64973769; called by muse, mutect2, varscan2
- ATP13A4 | c.325C>G p.L109V | Missense Mutation (SNP) | VAF 62/189 reads (33%) | SIFT tolerated (0.28); PolyPhen benign (0.012); catalogued as COSV99795315; called by muse, mutect2, varscan2
- BCL9 | c.535G>A p.V179M | Missense Mutation (SNP) | VAF 14/70 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs782506747, COSV52348873, COSV99325939; called by muse, mutect2, varscan2
- CCDC9 | c.271A>T p.K91* | Nonsense Mutation (SNP) | VAF 30/127 reads (24%) | catalogued as COSV99699871; called by muse, mutect2, varscan2
- CDH10 | c.1484C>A p.T495N | Missense Mutation (SNP) | VAF 28/270 reads (10%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.476); catalogued as COSV100053313; called by muse, varscan2
- CDH10 | c.1442A>T p.D481V | Missense Mutation (SNP) | VAF 36/290 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100053315; called by muse, varscan2
- CDH19 | c.87G>C p.K29N | Missense Mutation (SNP) | VAF 21/64 reads (33%) | SIFT tolerated (0.11); PolyPhen benign (0.014); catalogued as COSV100052454, COSV50954957; called by muse, mutect2, varscan2
- CDH2 | c.832G>C p.E278Q | Missense Mutation (SNP) | VAF 53/182 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV52271834, COSV99298758; called by muse, mutect2, varscan2
- CHD4 | c.4559C>T p.P1520L (on ENST00000357008 / NM_001363606.2; = p.P1533L on NM_001273.5) | Missense Mutation (SNP) | VAF 71/247 reads (29%) | SIFT tolerated (0.33); PolyPhen benign (0.003); catalogued as COSV100539359; called by muse, mutect2, varscan2
- CNTROB | c.79C>T p.L27F | Missense Mutation (SNP) | VAF 171/308 reads (56%) | SIFT deleterious, low confidence (0.05); PolyPhen possibly damaging (0.836); catalogued as COSV100366597; called by muse, mutect2, varscan2
- COL6A6 | c.2467G>C p.D823H | Missense Mutation (SNP) | VAF 31/120 reads (26%) | SIFT tolerated (0.12); PolyPhen benign (0.424); catalogued as COSV100651014; called by muse, mutect2, varscan2
- CREBBP | c.4666C>G p.L1556V | Missense Mutation (SNP) | VAF 51/165 reads (31%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.992); catalogued as COSV99272403; called by muse, varscan2
- CSMD3 | c.2423G>A p.R808Q (on ENST00000297405 / NM_001363185.1; = p.R704Q on NM_052900.3) | Missense Mutation (SNP) | VAF 39/147 reads (27%) | SIFT tolerated (0.07); PolyPhen benign (0.079); catalogued as rs1262637407, COSV99849520; called by muse, mutect2, varscan2
- CSPP1 | c.3352G>A p.A1118T (on ENST00000676605; = p.A1077T on NM_024790.6) | Missense Mutation (SNP) | VAF 43/136 reads (32%) | SIFT deleterious (0.03); PolyPhen benign (0.081); catalogued as COSV99140085; called by muse, mutect2, varscan2
- CYP2A13 | c.13G>A p.G5R | Missense Mutation (SNP) | VAF 19/75 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.888); catalogued as rs71579358, COSV100387051; called by muse, mutect2, varscan2
- DCST2 | c.563G>A p.W188* | Nonsense Mutation (SNP) | VAF 12/40 reads (30%) | catalogued as COSV99792310; called by muse, mutect2
- E2F4 | c.680C>T p.P227L | Missense Mutation (SNP) | VAF 55/165 reads (33%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as COSV100104337; called by muse, mutect2, varscan2
- ECM1 | c.488G>A p.R163Q | Missense Mutation (SNP) | VAF 141/422 reads (33%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as rs781095324, COSV100682346; called by muse, mutect2, varscan2
- FAM90A1 | c.216C>G p.N72K | Missense Mutation (SNP) | VAF 83/257 reads (32%) | SIFT tolerated (0.11); PolyPhen benign (0); catalogued as COSV100274551; called by muse, mutect2, varscan2
- FASTKD3 | c.752T>A p.F251Y | Missense Mutation (SNP) | VAF 44/355 reads (12%) | SIFT tolerated (0.06); PolyPhen benign (0.115); catalogued as COSV99242154; called by muse, mutect2, varscan2
- FBXO8 | c.638C>T p.A213V | Missense Mutation (SNP) | VAF 18/106 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV101183758; called by muse, mutect2, varscan2
- FIZ1 | c.721G>T p.A241S | Missense Mutation (SNP) | VAF 9/20 reads (45%) | SIFT tolerated (0.72); PolyPhen benign (0.176); catalogued as rs767369020, COSV55607227, COSV55609246; called by muse, mutect2, varscan2
- FMN2 | c.4464G>A p.M1488I | Missense Mutation (SNP) | VAF 31/144 reads (22%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.782); catalogued as COSV100147434; called by muse, mutect2, varscan2
- FTSJ3 | c.245C>T p.P82L | Missense Mutation (SNP) | VAF 139/252 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs769382758, COSV100037480; called by muse, mutect2, varscan2
- GAPVD1 | c.3409C>T p.P1137S (on ENST00000394104; = p.P1146S on NM_015635.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 116/217 reads (53%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.553); catalogued as COSV99783867; called by muse, mutect2, varscan2
- GNPTAB | c.3347T>C p.M1116T | Missense Mutation (SNP) | VAF 8/54 reads (15%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.582); catalogued as rs767741989, COSV100172466; called by muse, mutect2, varscan2
- GPR137C | c.839A>C p.N280T | Missense Mutation (SNP) | VAF 37/132 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.793); catalogued as COSV100397943; called by muse, mutect2, varscan2
- HIVEP1 | c.1A>T p.M1? | Translation Start Site (SNP) | VAF 37/148 reads (25%) | SIFT deleterious (0.02); PolyPhen benign (0.069); catalogued as COSV101045814; called by muse, mutect2, varscan2
- IFT172 | c.4867A>G p.T1623A | Missense Mutation (SNP) | VAF 53/181 reads (29%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.895); catalogued as rs750991615, COSV51996882; called by muse, mutect2, varscan2
- KATNAL1 | c.1069G>A p.A357T | Missense Mutation (SNP) | VAF 21/74 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV101017240, COSV66064072; called by muse, mutect2, varscan2
- KIF5B | c.652C>G p.Q218E | Missense Mutation (SNP) | VAF 10/138 reads (7%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100192465; called by muse, mutect2
- KLHL1 | c.782A>T p.N261I | Missense Mutation (SNP) | VAF 51/110 reads (46%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.555); catalogued as COSV100918239; called by muse, mutect2, varscan2
- KMT2D | c.15340C>T p.H5114Y | Missense Mutation (SNP) | VAF 37/131 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV56429389; called by muse, mutect2, varscan2
- LRP1B | c.12224-2A>T p.X4075_splice | Splice Site (SNP) | VAF 19/57 reads (33%) | catalogued as COSV101261691; called by muse, mutect2, varscan2
- LRP1B | c.1932G>T p.M644I | Missense Mutation (SNP) | VAF 39/165 reads (24%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.977); catalogued as COSV101261693, COSV67269009; called by muse, mutect2, varscan2
- LRRC27 | c.1561G>A p.G521R | Missense Mutation (SNP) | VAF 22/49 reads (45%) | SIFT tolerated, low confidence (0.39); PolyPhen benign (0); catalogued as COSV100889946; called by muse, mutect2, varscan2
- MAPK8IP3 | c.1690G>A p.V564I | Missense Mutation (SNP) | VAF 90/281 reads (32%) | SIFT tolerated (0.34); PolyPhen benign (0.006); catalogued as rs777933816, COSV99169823; called by muse, mutect2, varscan2
- MCM3 | c.2448C>A p.F816L (on ENST00000229854 / NM_001366374.2; = p.F806L on NM_002388.6 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 39/157 reads (25%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.46); catalogued as COSV100009119; called by muse, mutect2, varscan2
- MDN1 | c.12759C>T p.L4253= | Splice Region (SNP) | VAF 29/101 reads (29%) | catalogued as rs375471963, COSV101021879; called by muse, mutect2, varscan2
- MFHAS1 | c.151C>T p.P51S | Missense Mutation (SNP) | VAF 4/9 reads (44%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.041); catalogued as COSV99359992; called by muse, mutect2, varscan2
- MPP2 | c.892C>T p.H298Y (on ENST00000461854 / NM_001278372.2; = p.H274Y on NM_005374.5) | Missense Mutation (SNP) | VAF 116/180 reads (64%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.864); catalogued as rs762079137, COSV99290878; called by muse, mutect2, varscan2
- MUC5AC | c.395C>T p.T132M | Missense Mutation (SNP) | VAF 14/45 reads (31%) | SIFT tolerated (0.06); catalogued as rs760860834, COSV100650648, COSV100650724; called by muse, mutect2, varscan2
- MYH14 | c.4319G>A p.R1440H | Missense Mutation (SNP) | VAF 9/32 reads (28%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.734); catalogued as rs757839485, COSV99222387; called by muse, varscan2
- MYH4 | c.3197C>T p.A1066V | Missense Mutation (SNP) | VAF 146/300 reads (49%) | SIFT deleterious (0.01); PolyPhen benign (0.119); catalogued as COSV99702405; called by muse, mutect2, varscan2
- NETO1 | c.872C>A p.P291H | Missense Mutation (SNP) | VAF 29/81 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100199854; called by muse, mutect2, varscan2
- NPAP1 | c.1583C>T p.S528F | Missense Mutation (SNP) | VAF 108/438 reads (25%) | SIFT tolerated (0.56); PolyPhen benign (0.003); catalogued as rs865895928, COSV61506356; called by muse, mutect2, varscan2
- NPFFR2 | c.754C>A p.P252T | Missense Mutation (SNP) | VAF 99/405 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58151771; called by muse, mutect2, varscan2
- OR10X1 | c.508T>C p.F170L | Missense Mutation (SNP) | VAF 26/90 reads (29%) | SIFT tolerated (1); PolyPhen benign (0.023); catalogued as COSV100936717; called by muse, mutect2, varscan2
- OR13C9 | c.208G>T p.D70Y | Missense Mutation (SNP) | VAF 50/182 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.834); catalogued as COSV52240643, COSV99403574; called by muse, mutect2, varscan2
- OR51B2 | c.569T>G p.I190R | Missense Mutation (SNP) | VAF 29/84 reads (35%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.973); catalogued as COSV100173550; called by muse, mutect2, varscan2
- OR5P2 | c.521dup p.C175Lfs*2 | Frame Shift Ins (INS) | VAF 34/116 reads (29%) | catalogued as rs765996302; called by mutect2, pindel, varscan2
- PARP9 | c.1224T>G p.H408Q | Missense Mutation (SNP) | VAF 24/90 reads (27%) | SIFT tolerated (0.54); PolyPhen benign (0.01); catalogued as COSV100831291; called by muse, mutect2, varscan2
- PHF23 | c.947C>T p.S316F | Missense Mutation (SNP) | VAF 466/780 reads (60%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.767); catalogued as COSV50038191, COSV99138922; called by muse, mutect2, varscan2
- PKP3 | c.2140C>T p.P714S | Missense Mutation (SNP) | VAF 25/101 reads (25%) | SIFT tolerated (0.83); PolyPhen benign (0.003); catalogued as COSV100230356; called by muse, mutect2, varscan2
- PLEKHG4B | c.2779A>G p.M927V (on ENST00000283426; = p.M1283V on NM_052909.5) | Missense Mutation (SNP) | VAF 50/70 reads (71%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); catalogued as rs778365236, COSV99361208; called by muse, mutect2, varscan2
- PLEKHH2 | c.3779C>T p.A1260V | Missense Mutation (SNP) | VAF 64/166 reads (39%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.702); catalogued as COSV99175170; called by muse, mutect2, varscan2
- PNMA1 | c.722A>G p.E241G | Missense Mutation (SNP) | VAF 43/167 reads (26%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.957); catalogued as COSV99679299; called by muse, mutect2, varscan2
- POM121C | c.2759C>T p.T920M (on ENST00000607367; = p.T678M on NM_001099415.3) | Missense Mutation (SNP) | VAF 27/126 reads (21%) | SIFT deleterious (0.04); PolyPhen benign (0.26); catalogued as rs1462074396; called by muse, mutect2, varscan2
- PRPF40B | c.2579G>A p.R860Q (on ENST00000380281; = p.R847Q on NM_012272.3) | Missense Mutation (SNP) | VAF 19/91 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.003); catalogued as rs753845877, COSV99527078; called by muse, mutect2, varscan2
- RAP1GDS1 | c.1651A>G p.I551V | Missense Mutation (SNP) | VAF 38/99 reads (38%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV99217477; called by muse, mutect2, varscan2
- REL | c.125A>T p.D42V | Missense Mutation (SNP) | VAF 57/216 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); catalogued as COSV99692457; called by muse, mutect2, varscan2
- RPS6KA5 | c.2401G>A p.V801I | Missense Mutation (SNP) | VAF 60/203 reads (30%) | PolyPhen benign (0.003); catalogued as COSV100003311; called by muse, mutect2, varscan2
- RTN4RL2 | c.798C>G p.D266E | Missense Mutation (SNP) | VAF 7/27 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.487); catalogued as COSV100625491; called by muse, mutect2, varscan2
- RUNX1T1 | c.1594G>T p.A532S (on ENST00000265814 / NM_001198628.1; = p.A505S on NM_004349.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 19/74 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99755370; called by muse, mutect2, varscan2
- SEPTIN12 | c.469C>T p.R157W | Missense Mutation (SNP) | VAF 52/206 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs765951766, COSV99190846; called by muse, mutect2
- SETDB1 | c.3408A>G p.I1136M | Missense Mutation (SNP) | VAF 27/119 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99645952; called by muse, mutect2, varscan2
- SFSWAP | c.1120C>T p.P374S | Missense Mutation (SNP) | VAF 66/211 reads (31%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.997); catalogued as COSV99906455; called by muse, mutect2, varscan2
- SIGLECL1 | c.128G>A p.G43E | Missense Mutation (SNP) | VAF 55/156 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.77); catalogued as COSV100324028; called by muse, mutect2, varscan2
- SPAG17 | c.962T>A p.M321K | Missense Mutation (SNP) | VAF 37/117 reads (32%) | SIFT tolerated (0.08); PolyPhen benign (0.08); catalogued as COSV100310763; called by muse, mutect2, varscan2
- SRPX | c.611A>T p.E204V | Missense Mutation (SNP) | VAF 5/40 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.583); catalogued as COSV100656283; called by muse, mutect2, varscan2
- STARD10 | c.514C>T p.L172F | Missense Mutation (SNP) | VAF 36/86 reads (42%) | SIFT tolerated (0.06); PolyPhen benign (0.445); catalogued as COSV58325961; called by muse, mutect2, varscan2
- STX1A | c.685A>T p.M229L | Missense Mutation (SNP) | VAF 16/42 reads (38%) | SIFT tolerated (0.13); PolyPhen benign (0.021); catalogued as COSV99736971; called by muse, mutect2, varscan2
- STX8 | c.491G>A p.R164H | Missense Mutation (SNP) | VAF 118/251 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs143935601; called by muse, mutect2, varscan2
- SUPT16H | c.1420C>T p.R474* | Nonsense Mutation (SNP) | VAF 61/240 reads (25%) | catalogued as COSV99360261; called by muse, mutect2, varscan2
- SZT2 | c.8069A>T p.H2690L (on ENST00000634258 / NM_001365999.1; = p.H2633L on NM_015284.4) | Missense Mutation (SNP) | VAF 56/180 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV100987700; called by muse, mutect2, varscan2
- TBC1D8 | c.2846G>C p.R949T | Missense Mutation (SNP) | VAF 47/135 reads (35%) | SIFT tolerated (0.25); PolyPhen benign (0.028); catalogued as COSV99961608; called by muse, mutect2, varscan2
- TBXA2R | c.331G>A p.V111I | Missense Mutation (SNP) | VAF 13/44 reads (30%) | SIFT tolerated (0.1); PolyPhen benign (0.005); catalogued as rs1249340215, COSV64344628; called by muse, mutect2, varscan2
- TENM1 | c.2208C>A p.C736* | Nonsense Mutation (SNP) | VAF 4/62 reads (6%) | catalogued as COSV100951136; called by muse, mutect2
- TERF1 | c.323T>G p.I108S | Missense Mutation (SNP) | VAF 42/142 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.783); catalogued as COSV99401456; called by muse, mutect2, varscan2
- TIAL1 | c.791C>T p.T264M | Missense Mutation (SNP) | VAF 40/75 reads (53%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.756); catalogued as rs148932828; called by muse, mutect2, varscan2
- TM4SF1 | c.491C>T p.S164F | Missense Mutation (SNP) | VAF 46/137 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV100543062, COSV59524692; called by muse, mutect2, varscan2
- TNC | c.1168G>A p.G390R | Missense Mutation (SNP) | VAF 36/145 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs536685730, COSV100406365; called by muse, mutect2, varscan2
- TNFAIP6 | c.758C>T p.S253F | Missense Mutation (SNP) | VAF 66/241 reads (27%) | SIFT deleterious (0.04); PolyPhen benign (0.014); catalogued as COSV99694111; called by muse, mutect2, varscan2
- TNFRSF6B | c.678C>G p.I226M | Missense Mutation (SNP) | VAF 11/61 reads (18%) | SIFT tolerated (0.18); PolyPhen benign (0.031); catalogued as rs764972813, COSV99423366; called by muse, mutect2, varscan2
- TRAF3IP2 | c.44C>T p.P15L | Missense Mutation (SNP) | VAF 49/184 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100389938; called by muse, mutect2, varscan2
- TRPC7 | c.1413G>A p.W471* | Nonsense Mutation (SNP) | VAF 36/87 reads (41%) | catalogued as COSV100726065; called by muse, mutect2, varscan2
- TRPM2 | c.3202C>T p.H1068Y | Missense Mutation (SNP) | VAF 36/121 reads (30%) | SIFT tolerated (0.76); PolyPhen benign (0.08); catalogued as COSV100309389; called by muse, mutect2, varscan2
- UGT1A1 | c.748_749insGGACAGTCAC p.S250Wfs*11 | Frame Shift Ins (INS) | VAF 45/272 reads (17%) | catalogued as COSV100531172; called by mutect2, pindel, varscan2
- VPS13D | c.10297A>T p.I3433F | Missense Mutation (SNP) | VAF 95/334 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0.055); catalogued as COSV99169733; called by muse, mutect2, varscan2
- WDR12 | c.558A>T p.R186S | Missense Mutation (SNP) | VAF 60/200 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV99651271; called by muse, mutect2, varscan2
- XPR1 | c.1334A>G p.Y445C | Missense Mutation (SNP) | VAF 37/137 reads (27%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.976); catalogued as COSV100851529; called by muse, mutect2, varscan2
- ZBTB41 | c.1792C>T p.H598Y | Missense Mutation (SNP) | VAF 39/174 reads (22%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.945); catalogued as COSV100963481; called by muse, mutect2, varscan2
- ZC3H7B | c.1064C>T p.S355L | Missense Mutation (SNP) | VAF 24/97 reads (25%) | SIFT tolerated (0.11); PolyPhen benign (0.084); catalogued as rs767664599, COSV100687842; called by muse, mutect2, varscan2
- ZFYVE26 | c.4286C>T p.A1429V | Missense Mutation (SNP) | VAF 84/315 reads (27%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.665); catalogued as COSV100720718; called by muse, mutect2, varscan2
- ZMYM2 | c.3527A>G p.N1176S | Missense Mutation (SNP) | VAF 17/34 reads (50%) | SIFT tolerated (0.08); PolyPhen benign (0.001); catalogued as rs1211777859, COSV101244143; called by muse, mutect2, varscan2
- ZNF236 | c.3470C>T p.A1157V | Missense Mutation (SNP) | VAF 13/39 reads (33%) | SIFT tolerated (0.57); PolyPhen benign (0.06); catalogued as rs542819528, COSV99471349; called by muse, mutect2, varscan2
- ZNF266 | c.1550A>G p.E517G | Missense Mutation (SNP) | VAF 48/173 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.336); catalogued as COSV100749450; called by muse, mutect2, varscan2
- ZNF292 | c.6307G>C p.E2103Q | Missense Mutation (SNP) | VAF 31/129 reads (24%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.867); catalogued as COSV100371423; called by muse, mutect2, varscan2
- ZNF578 | c.1378T>G p.C460G | Missense Mutation (SNP) | VAF 26/108 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV101405125; called by muse, mutect2, varscan2
- ZNF778 | c.394C>T p.L132F | Missense Mutation (SNP) | VAF 15/55 reads (27%) | SIFT tolerated (0.12); PolyPhen benign (0); catalogued as COSV100124705; called by muse, mutect2, varscan2
- ACSF2 | c.810dup p.K271Qfs*25 | Frame Shift Ins (INS) | VAF 37/348 reads (11%) | called by mutect2, pindel, varscan2
- ADGRF4 | c.1309dup p.Y437Lfs*28 | Frame Shift Ins (INS) | VAF 89/348 reads (26%) | called by mutect2, pindel, varscan2
- FAF1 | c.957dup p.S320Ifs*11 | Frame Shift Ins (INS) | VAF 43/186 reads (23%) | called by mutect2, pindel, varscan2
- KLHL31 | c.1767del p.E590Sfs*29 | Frame Shift Del (DEL) | VAF 34/134 reads (25%) | called by mutect2, pindel, varscan2
- MAN1B1 | c.466-2A>C p.X156_splice | Splice Site (SNP) | VAF 28/54 reads (52%) | called by muse, varscan2
- PLPP3 | c.345del p.S116Rfs*36 | Frame Shift Del (DEL) | VAF 25/123 reads (20%) | called by mutect2, pindel, varscan2
- RASGRP1 | c.1457dup p.D487Gfs*10 | Frame Shift Ins (INS) | VAF 29/67 reads (43%) | called by mutect2, pindel, varscan2
- SLC39A7 | c.1382dup p.M461Ifs*9 | Frame Shift Ins (INS) | VAF 24/135 reads (18%) | called by mutect2, pindel, varscan2
- SPG11 | c.6581A>T p.D2194V | Missense Mutation (SNP) | VAF 8/17 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2
- ANO1 | c.2443C>T p.L815= | Silent (SNP) | VAF 25/395 reads (6%) | catalogued as COSV100797541; called by muse, mutect2
- ARHGAP29 | c.138G>A p.K46= | Silent (SNP) | VAF 60/175 reads (34%) | catalogued as COSV99559160; called by muse, mutect2, varscan2
- CELSR2 | c.3030C>T p.H1010= | Silent (SNP) | VAF 24/146 reads (16%) | catalogued as rs751855828, COSV99604853; called by muse, mutect2, varscan2
- CFAP221 | c.1816C>A p.R606= | Silent (SNP) | VAF 26/90 reads (29%) | catalogued as COSV54657856, COSV99733228; called by muse, mutect2, varscan2
- DIO1 | c.405G>A p.Q135= | Silent (SNP) | VAF 103/315 reads (33%) | catalogued as COSV100499003; called by muse, mutect2, varscan2
- DRAM1 | c.288T>C p.S96= | Silent (SNP) | VAF 27/118 reads (23%) | catalogued as COSV99315866; called by muse, mutect2, varscan2
- FAM47A | c.807T>G p.S269= | Silent (SNP) | VAF 26/56 reads (46%) | catalogued as COSV100650108; called by muse, mutect2, varscan2
- HJURP | c.2022G>A p.R674= | Silent (SNP) | VAF 52/170 reads (31%) | catalogued as COSV100982648; called by muse, mutect2, varscan2
- KDM2A | c.705C>T p.P235= | Silent (SNP) | VAF 6/48 reads (13%) | catalogued as rs767630504, COSV67082851; called by mutect2, varscan2
- METRNL | c.393A>G p.V131= | Silent (SNP) | VAF 91/146 reads (62%) | catalogued as COSV100193883; called by muse, mutect2, varscan2
- MYH7 | c.5205C>T p.S1735= | Silent (SNP) | VAF 49/183 reads (27%) | catalogued as COSV100806748; called by muse, mutect2, varscan2
- NCOA1 | c.468C>G p.V156= | Silent (SNP) | VAF 29/119 reads (24%) | catalogued as COSV99947193; called by muse, mutect2, varscan2
- NLRP12 | c.252C>T p.D84= | Silent (SNP) | VAF 98/342 reads (29%) | catalogued as COSV100145978; called by muse, mutect2, varscan2
- NUP88 | c.843C>T p.I281= | Silent (SNP) | VAF 91/164 reads (55%) | catalogued as COSV99852026; called by muse, mutect2, varscan2
- OR4C46 | c.195C>T p.S65= | Silent (SNP) | VAF 93/409 reads (23%) | catalogued as rs759331911, COSV60218597, COSV60219427; called by muse, mutect2, varscan2
- OR56A3 | c.771C>T p.T257= | Silent (SNP) | VAF 72/321 reads (22%) | catalogued as rs754322483, COSV100290386, COSV61569525; called by muse, mutect2, varscan2
- PAPOLB | c.1371C>T p.L457= | Silent (SNP) | VAF 97/225 reads (43%) | catalogued as COSV101271633; called by muse, mutect2
- PAX6 | c.579C>T p.N193= | Silent (SNP) | VAF 35/142 reads (25%) | catalogued as rs367589686, COSV53794487; called by muse, mutect2, varscan2
- PDZD2 | c.2184A>G p.E728= | Silent (SNP) | VAF 12/132 reads (9%) | catalogued as COSV99226933; called by muse, mutect2
- POU6F2 | c.339C>A p.G113= | Silent (SNP) | VAF 103/385 reads (27%) | catalogued as COSV68869266; called by muse, mutect2, varscan2
- PPP1R1C | c.123C>G p.L41= | Silent (SNP) | VAF 95/309 reads (31%) | catalogued as COSV99724418; called by muse, mutect2, varscan2
- RAD9B | c.1149A>G p.A383= | Silent (SNP) | VAF 40/170 reads (24%) | catalogued as COSV100799460; called by muse, mutect2, varscan2
- RIOX1 | c.93C>T p.A31= | Silent (SNP) | VAF 18/49 reads (37%) | catalogued as rs762445621, COSV100408128, COSV58373647; called by muse, mutect2, varscan2
- ROPN1 | c.174A>G p.R58= | Silent (SNP) | VAF 48/162 reads (30%) | catalogued as COSV99481628; called by muse, mutect2, varscan2
- SEC16A | c.6897A>G p.L2299= | Silent (SNP) | VAF 8/18 reads (44%) | catalogued as COSV99260323; called by muse, mutect2, varscan2
- SLC6A12 | c.1575C>T p.Y525= | Silent (SNP) | VAF 44/164 reads (27%) | catalogued as rs1231446451, COSV100675021; called by muse, mutect2, varscan2
- SNX4 | c.1029G>A p.E343= | Silent (SNP) | VAF 45/164 reads (27%) | catalogued as COSV99305323; called by muse, mutect2, varscan2
- SPEG | c.8905C>T p.L2969= | Silent (SNP) | VAF 21/85 reads (25%) | catalogued as COSV100405823, COSV56680805; called by muse, mutect2, varscan2
- TOR1AIP2 | c.819G>A p.L273= | Silent (SNP) | VAF 30/177 reads (17%) | catalogued as COSV100857551; called by muse, mutect2, varscan2
- TRPM6 | c.2979G>A p.V993= | Silent (SNP) | VAF 34/70 reads (49%) | catalogued as COSV100667047; called by muse, mutect2, varscan2
- TUBB2A | c.339C>T p.V113= | Silent (SNP) | VAF 15/89 reads (17%) | catalogued as rs1250669469, COSV100373957; called by muse, mutect2, varscan2
- WDR17 | c.1695T>C p.H565= | Silent (SNP) | VAF 42/220 reads (19%) | catalogued as rs1279911501, COSV99708369; called by muse, mutect2, varscan2
- ZFHX4 | c.1641T>C p.S547= | Silent (SNP) | VAF 11/49 reads (22%) | catalogued as COSV99268406; called by muse, mutect2, varscan2
- ZNF585A | c.1767C>T p.R589= (on ENST00000292841 / NM_001288800.2; = p.R534= on NM_152655.3) | Silent (SNP) | VAF 32/130 reads (25%) | catalogued as COSV99493647; called by muse, mutect2, varscan2
- TIRAP | c.646+47A>T | Intron (SNP) | VAF 16/41 reads (39%) | catalogued as COSV101201681; called by muse, mutect2, varscan2
- UBTFL2 | n.847T>C | RNA (SNP) | VAF 37/80 reads (46%) | called by muse, mutect2, varscan2
